TCGA case TCGA-G3-A5SK — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Alberta Health Services. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/24259d55-20ac-4359-861f-dcad7ad88cee

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Canada; Age at index: 58 years; Vital status: Alive.

Diagnoses (3)
1. Hepatocellular carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 58.4 years (21,320 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: T1; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: G1; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Child pugh classification: A; Ishak fibrosis score: 6 - Established Cirrhosis.
   Pathology details: Additional pathology findings: Inflammation; Consistent pathology review: Yes.
   Treatment given: Treatment type: Ablation, Radiofrequency; Days to treatment start: 575 days (1.6 years); Number of cycles: 1; Lesions treated number: 1.
   Treatment given: Treatment type: Chemoembolization; Therapeutic agents: Doxorubicin; Days to treatment start: 671 days (1.8 years); Embolic agent: Plastic Beads.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Hepatocellular carcinoma, NOS), site: Liver. Age at diagnosis: 59.7 years (21,803 days); Days to diagnosis: 483 days (1.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Ablation or Embolization, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Organ Transplantation to Liver, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.
3. Recurrence of diagnosis 1 (Hepatocellular carcinoma, NOS), site: Liver. Age at diagnosis: 60.1 years (21,936 days); Days to diagnosis: 616 days (1.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Ablation or Embolization, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Organ Transplantation to Liver, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (5 entries)
- Days to follow up: 302 days; Disease response: Tumor Free.
- Day 483 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Progression or recurrence anatomic site: Liver; Days to recurrence: 483 days (1.3 years).
- Day 616 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Progression or recurrence anatomic site: Liver; Days to recurrence: 616 days (1.7 years).
- Days to follow up: 744 days (2.0 years); Disease response: With Tumor.
- ECOG performance status: 0.

Molecular and laboratory tests
- Prothrombin time (INR, as labelled on the TCGA clinical form) 1.1 [Blood test normal range lower: 0.9; Blood test normal range upper: 1.1].
- Creatinine 0.6 mg/dL [Blood test normal range lower: 0.6; Blood test normal range upper: 1.4].
- Albumin 3.3 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.3; Blood test normal range upper: 4.8].
- Platelets 106 (unit not recorded by GDC) [Blood test normal range lower: 150; Blood test normal range upper: 400].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Hepatitis C Infection.
- Timepoint category: Initial Diagnosis; Weight: 67 kg; Height: 169 cm; BMI: 23.5.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-G3-A5SK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 650 mg.
  Slide TCGA-G3-A5SK-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-G3-A5SK-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-G3-A5SK-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Histologic diagnosis: Hepatocellular Carcinoma; Definitive surgical procedure: Segmentectomy, Single; Hepatic inflammation adj tissue: Mild.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor.
- Ablations, Ablation, Ablation treatments: Ablation performed indicator: Yes.
- Ablations, Ablation, Ablation treatments, Ablation treatment: Ablation type: Radiofrequency Ablation; Treatment cycles count: 1; Lesions count: 1.
- Ablations, Ablation, Embolization treatments: Embolization performed indicator: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 744 days; disease-specific survival: no event (censored), 744 days; disease-free interval: event (new tumor event after initially disease-free), 483 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 483 days.
